Gene-level copy-number profile of tumor specimen C3L-04090-01 (profiled together with C3L-04090-02, C3L-04090-03, C3L-04090-04) from CPTAC case C3L-04090, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.5 years (26,123 days).
Specimen C3L-04090-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7e08087c-86c7-42ae-8e9b-8d3708cc4286.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04090-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/87426870-a726-4830-a0fd-96a35af25165

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 3,237; copy number 2: 47,601; copy number 3: 7,444; copy number 4: 59; copy number 47: 5; copy number 49: 4.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–21,077,942, 3 genes: HACD4, IFNNP1, IFNB1.
- chr9:21,160,235–21,202,205, 6 genes: Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7.
- chr9:21,278,050–21,638,676, 20 genes: IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30.
- chr9:21,802,636–23,438,700, 20 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,656,358–55,260,256, 9 genes, copy number 47–49: RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.

Autosomal genes at a single copy (total copy number 1): 3,237. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
